Somatic mutation profile of tumor specimen MBCProject_6838_T1_WES (aliquot MBCProject_6838_T1_WES_1) from CMI case MBCProject_6838, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 58.0 years (21,200 days).
Specimen MBCProject_6838_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc64f9d7-6d16-4771-a4d1-3186a736fe72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6838_SALIVA (Saliva), aliquot MBCProject_6838_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f586261b-4421-4742-b2bb-b34e8623508d

The open-access MAF lists 48 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Intron 9, Silent 7, 5'UTR 3, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD34A | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782102250; called by muse, mutect2, varscan2
- ATP6V0A4 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 92/441 reads (21%) | catalogued as rs746304347; called by muse, mutect2, varscan2
- C14orf28 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57333582; called by muse, mutect2, varscan2
- DST | c.7421C>T p.A2474V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs374059299; called by mutect2, varscan2
- HSF1 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 157/488 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs1355120987; called by muse, mutect2, varscan2
- KCTD12 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1439478122, COSV58524522; called by muse, mutect2, varscan2
- NAV2 | c.2360C>T p.T787M (on ENST00000396087 / NM_001244963.2; = p.T764M on NM_145117.5) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs180786689; called by muse, mutect2
- PCDHGB2 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 51/520 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as rs1259552110, COSV54044139; called by muse, mutect2
- RIN3 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.133); catalogued as rs763772852, COSV53645407; called by muse, mutect2, varscan2
- RYR1 | c.2251G>A p.V751M | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767667578, COSV100614018, COSV62104732; called by muse, mutect2, varscan2
- WDR81 | c.4724G>A p.R1575Q (on ENST00000409644 / NM_001163809.2; = p.R524Q on NM_152348.4) | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1484787623, COSV58484196; called by muse, mutect2, varscan2
- ZNF43 | c.670A>C p.N224H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1350218141, COSV61683499; called by muse, mutect2, varscan2
- ZNF710 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1229529877; called by muse, mutect2
- CAMSAP2 | c.799C>A p.P267T (on ENST00000236925 / NM_001297707.2; = p.P256T on NM_203459.3) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DNAH2 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- DPCD | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPPL1 | c.1745T>C p.L582P | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- KCNV2 | c.1399A>T p.T467S | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- KMT2C | c.14614_14620del p.S4872Gfs*31 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel
- MUC22 | c.2596A>T p.T866S | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.29); called by muse, mutect2, varscan2
- OR4S1 | c.617T>C p.L206S | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLRG1 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- REV3L | c.5404C>A p.H1802N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SOX6 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TAF1 | c.3270C>A p.N1090K (on ENST00000373790 / NM_138923.4; = p.N1111K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TARBP1 | c.4841T>C p.L1614P | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); called by mutect2, varscan2
- UBE2W | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BRD9 | c.516A>C p.G172= | Silent (SNP) | VAF 53/127 reads (42%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.33C>A p.L11= | Silent (SNP) | VAF 63/203 reads (31%) | catalogued as COSV99766481; called by muse, mutect2, varscan2
- KIAA1549 | c.1617C>G p.G539= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- LAMA4 | c.279C>T p.D93= | Silent (SNP) | VAF 67/365 reads (18%) | catalogued as rs397516726, COSV54570965; ClinVar: likely benign; called by muse, mutect2, varscan2
- MCRIP2 | c.462G>A p.A154= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs763306329; called by muse, mutect2, varscan2
- MSN | c.1002G>A p.E334= | Silent (SNP) | VAF 17/181 reads (9%) | catalogued as rs113359990, COSV64303140; called by muse, mutect2
- PACS2 | c.2580C>T p.D860= | Silent (SNP) | VAF 23/372 reads (6%) | catalogued as rs201014934; called by muse, mutect2
- AC092329.3 | c.-211-656A>G | Intron (SNP) | VAF 7/51 reads (14%) | catalogued as rs963015692, COSV68024692; called by muse, mutect2
- ACBD5 | chr10:27196135 A>G | 3'Flank (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2
- ADAM9 | c.333+66G>A | Intron (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- CCDC40 | c.2619+9G>A | Intron (SNP) | VAF 212/642 reads (33%) | catalogued as rs752961530; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 33/220 reads (15%) | catalogued as rs1291738365; called by muse, mutect2
- EPO | c.-24G>A | 5'UTR (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- FBXO16 | c.136-1544A>G | Intron (SNP) | VAF 8/90 reads (9%) | catalogued as rs1447874073; called by muse, mutect2
- PROS1 | c.77-1331G>A | Intron (SNP) | VAF 18/73 reads (25%) | catalogued as rs977858676; called by muse, mutect2, varscan2
- RAD51C | chr17:58692583 del CGCACGCCCCAGCGAGGGCGTGCGGAGTTTGGCTGCTCCGG | 5'UTR (DEL) | VAF 60/406 reads (15%) | called by mutect2, pindel
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 7/27 reads (26%) | catalogued as rs1356395055; called by muse, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 16/212 reads (8%) | catalogued as rs910081914; called by muse, mutect2
- RNF217-AS1 | n.2164A>T | RNA (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- TMEM86A | c.-55G>A | 5'UTR (SNP) | VAF 121/212 reads (57%) | called by muse, varscan2
- XPO5 | c.2678-356T>C | Intron (SNP) | VAF 12/144 reads (8%) | catalogued as rs1242378776, COSV54830476; called by muse, mutect2
